EXCEPTIONAL_RESPONDERS case ER-ADXD — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5b86bb3a-7072-4380-ba91-73c384697cda

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1941; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Overlapping lesion of colon; Site of resection or biopsy: Overlapping lesion of colon; Classification of tumor: primary; Age at diagnosis: 69.4 years (25,357 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC clinical stage: Stage IV; Prior malignancy: no; Days to last follow up: 1,873 days (5.1 years); Days to best overall response: 229 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Bevacizumab + Fluorouracil + Leucovorin Calcium + Oxaliplatin; Days to treatment start: 55 days; Days to treatment end: 229 days.

Follow-up (1 entry)
- Days to follow up: 1,873 days (5.1 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 1,873 days (5.1 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ADXD-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-ADXD-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-ADXD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-ADXD-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 30; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
